Somatic mutation profile of tumor specimen TCGA-ZM-AA0B-01A (aliquot TCGA-ZM-AA0B-01A-11D-A435-10) from TCGA case TCGA-ZM-AA0B, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 32.4 years (11,820 days).
Specimen TCGA-ZM-AA0B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd04022a-51bf-4f78-b6fd-51ffd9fb0938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0B-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0B-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee69a18-94d2-4aca-ba8d-0b3e19af74ee

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 3'UTR 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1C2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs201753402; called by muse, mutect2, varscan2
- HELZ | c.3629C>G p.P1210R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100698538; called by muse, mutect2, varscan2
- MAPK15 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs376274608; called by mutect2, varscan2
- ACOT9 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- C1orf56 | c.371_380del p.L124Rfs*14 | Frame Shift Del (DEL) | VAF 34/60 reads (57%) | called by mutect2, pindel, varscan2
- DDX17 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EIF2B2 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A27 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ARL2BP | c.241C>T p.L81= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- FUT8 | c.192C>T p.A64= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs372888976; called by mutect2, varscan2
- KCNH5 | c.669T>C p.I223= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- RBM33 | c.3120G>T p.G1040= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs1563181696; called by muse, mutect2, varscan2
- ZNF653 | c.1188C>T p.C396= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs747621823; called by muse, mutect2, varscan2
- ATP13A2 | c.*217C>T | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, varscan2
- NUCB2 | c.*14C>G | 3'UTR (SNP) | VAF 34/258 reads (13%) | called by muse, mutect2, varscan2
- VPS25 | c.-7_5dup | 5'UTR (INS) | VAF 20/111 reads (18%) | called by mutect2, varscan2
- ZNF74 | c.-262C>T | 5'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
